Somatic mutation profile of tumor specimen TCGA-06-6389-01A (aliquot TCGA-06-6389-01A-11D-1696-08) from TCGA case TCGA-06-6389, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,248 days).
Specimen TCGA-06-6389-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d2cb4a2-ead1-4e99-9e9f-5f47a41cf8d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6389-10A (Blood Derived Normal), aliquot TCGA-06-6389-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaa65ead-b512-4aab-b69a-64c904603c96

The open-access MAF lists 42 somatic variants for this specimen: 27 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 14, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 37/40 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACE2 | c.1741G>A p.V581I | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV53024143; called by muse, mutect2, varscan2
- AMD1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs753517621, COSV64387769; called by muse, mutect2, varscan2
- CACNA2D2 | c.2290G>A p.G764S (on ENST00000479441 / NM_001174051.3; = p.G757S on NM_006030.4) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs906863087, COSV56563777; called by muse, mutect2, varscan2
- COL4A6 | c.1079A>G p.N360S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV57862050; called by muse, mutect2, varscan2
- FCN1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs777571891, COSV65662178; called by muse, mutect2, varscan2
- GABRQ | c.941A>C p.H314P | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV64781343; called by muse, mutect2, varscan2
- IFT172 | c.4682_4683del p.S1561Cfs*18 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | catalogued as rs1468837226; called by mutect2, pindel
- IL7R | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV57407044, COSV57407423; called by muse, mutect2, varscan2
- KRTAP22-1 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 36/181 reads (20%) | PolyPhen benign (0); catalogued as COSV58182090, COSV58182288; called by muse, mutect2, varscan2
- PAK4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1189702999, COSV100426499; called by muse, mutect2
- PLCXD3 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV60605512, COSV60608765; called by muse, mutect2, varscan2
- RGR | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1254582525, COSV63893694; called by muse, mutect2, varscan2
- RNF148 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs370211791; called by mutect2, varscan2
- SIRPB1 | c.52A>T p.T18S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs976821695; called by muse, mutect2, varscan2
- TEX15 | c.1196T>A p.V399D (on ENST00000256246; = p.V782D on NM_001350162.2) | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56341625, COSV56343801; called by muse, mutect2, varscan2
- TMEM168 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1371233931; called by muse, mutect2, varscan2
- AHDC1 | c.2191G>T p.V731L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CYP1A2 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2
- HAS2 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 32/814 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.26); called by muse, mutect2
- KCNH7 | c.1236G>C p.W412C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KIF9 | c.1570T>C p.Y524H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- MIA3 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- NEK2 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLAGL2 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- SYBU | c.1858C>T p.P620S (on ENST00000276646 / NM_001099754.2; = p.P619S on NM_017786.6) | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC9 | c.3921A>C p.P1307= | Silent (SNP) | VAF 75/178 reads (42%) | catalogued as COSV53966081; called by muse, mutect2, varscan2
- C21orf91 | c.381A>G p.P127= | Silent (SNP) | VAF 46/242 reads (19%) | called by muse, mutect2, varscan2
- C9orf152 | c.357G>A p.T119= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs376699609, COSV68762674; called by muse, mutect2, varscan2
- CDH23 | c.5706T>C p.N1902= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs755451021; called by muse, mutect2, varscan2
- DNAH3 | c.3327G>A p.E1109= | Silent (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- EHMT2 | c.3546T>A p.I1182= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV57666528; called by muse, mutect2, varscan2
- HYDIN | c.6552C>T p.P2184= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs368359335; called by muse, mutect2, varscan2
- IL17B | c.364C>T p.L122= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV51002221; called by muse, mutect2
- LAMC2 | c.195C>T p.C65= | Silent (SNP) | VAF 169/428 reads (39%) | catalogued as COSV51453641; called by muse, mutect2, varscan2
- MFSD6L | c.1455C>T p.P485= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1212143369, COSV100319871; called by muse, mutect2
- NCAPH | c.126G>A p.A42= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs139287054, COSV99545546; called by muse, mutect2, varscan2
- OR2L2 | c.561C>G p.A187= | Silent (SNP) | VAF 17/305 reads (6%) | called by muse, mutect2
- P2RY10 | c.327C>T p.C109= | Silent (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- PHKA1 | c.1810T>C p.L604= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- OR2W5 | n.918G>A | RNA (SNP) | VAF 17/232 reads (7%) | catalogued as rs560353155; called by muse, mutect2
